Surgical pathology report (de-identified scan), TCGA case TCGA-HN-A2NL, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Ontario Institute for Cancer Research (OICR), specimen TCGA-HN-A2NL-01A (Primary Tumor).

Sample Type Tumour Primary

Sample Preparation	Fresh Frozen
Site of Primary (Event)	
Site of Tissue	Breast
Year of Sample Collection	
Age at Sample Collection (yrs)	56
Sample Comments	100-0-3 Carcinoma, infiltrating lobular, NOS 8520/3 Site: breast, NOS C50.9
Days to Procedure Date	0
Days to Diagnosis	7
Type of Procedure	Surgical resection
Site of Primary (Histology)	Left breast
Bilateral Disease	
Tumour Size (cm)	3.5
Histology	Other
Grade/Differentiation	Grade III (high - poorly differentiated)
Pathological T	T2
Pathological N	N0,NOS
Number of Nodes Sampled	3
Number of Nodes Positive	0
Clinical M	M0
Histology Comments	Infiltrating mammary carcinoma with lobular features No In Situ component.
SBR (Scarff-Bloom-Richardson) score	9
ER Status	Negative
PR Status	Negative
HER2 Status	Negative
Lymph Node Metastases	None Documented

hw
9/16/11

Source: NCI Genomic Data Commons file d564b817-5477-4013-93df-931e1e21622a (TCGA-HN-A2NL.CC1EE9E0-BC1A-46ED-A262-7A2B9CC8BBB1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).